Somatic mutation profile of tumor specimen 0D9W62 from CCDI case PBBIVA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.4 years (4,545 days).
Specimen 0D9W62: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bacf5b82-cbf4-4b6e-8802-012f0ae43364.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9W63 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0528255-3cb0-4378-9c36-9fa7bab0949b

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP4R3C | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 25/344 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.936); catalogued as COSV69080890; called by muse, mutect2
- HGF | c.1557C>T p.C519= | Silent (SNP) | VAF 48/149 reads (32%) | catalogued as rs1258858592, COSV55944770; called by muse, mutect2, varscan2
